Gene-level copy-number profile of tumor specimen ALCH-B2QK-TTP1-A from ALCHEMIST case ALCH-B2QK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Mixed invasive mucinous and non-mucinous adenocarcinoma; Age at diagnosis: 66.5 years (24,287 days).
Specimen ALCH-B2QK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f17b323f-6e5f-4972-a3f1-6334c048a000.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2QK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/bfd78267-c466-4894-a317-05bba843cfc7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 1: 7,274; copy number 2: 49,904; copy number 3: 1,100; copy number 4: 36; copy number 5: 2; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,474,973–13,516,270, 2 genes: LRRC38, AL354712.1.
- chr1:26,593,243–26,594,041, 2 genes: RN7SL679P, Y_RNA.
- chr2:43,812,472–43,838,865, 1 gene: ABCG5.
- chr2:130,690,133–130,718,831, 2 genes (within-gene range 0–2): FAR2P3, KLF2P3.
- chr3:147,386,046–147,406,809, 2 genes (within-gene range 0–2): ZIC4, ZIC4-AS1.
- chr4:25,529,177–25,623,601, 3 genes: AC105290.1, RNU7-126P, AC092436.1.
- chr5:100,388,853–100,389,938, 1 gene: AC113385.2.
- chr7:27,128,969–27,250,493, 30 genes (within-gene range 0–2): AC004080.6, HOXA-AS3, HOXA5, HOXA6, AC004080.5, HOXA7, AC004080.4, HOXA9, AC004080.3, HOXA10-AS, MIR196B, HOXA10, HOXA11, HOXA11-AS, AC004080.7, AC004080.14, AC004080.8, AC004080.2, AC004080.12, AC004080.15, AC004080.13, HOXA13, HOTTIP, AC004080.9, AC004080.16, AC004080.10, AC004080.11, AC004080.1, EVX1-AS, EVX1.
- chr7:55,731,100–55,773,288, 6 genes: Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1.
- chr7:129,756,266–129,785,185, 5 genes (within-gene range 0–2): RNA5SP244, MIR182, MIR96, MIR183, AC084864.1.
- chr8:101,686,547–101,689,093, 1 gene (within-gene range 0–2): AP000426.1.
- chr11:67,056,847–67,072,017, 1 gene: RHOD.
- chr12:6,532,290–6,538,374, 3 genes: AC006064.3, GAPDH, AC006064.4.
- chr12:6,543,504–6,544,931, 1 gene (within-gene range 0–2): AC006064.1.
- chr13:35,697,487–35,699,938, 1 gene: LINC00445.
- chr16:30,023,334–30,052,978, 2 genes: C16orf92, TLCD3B.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:45,784,280–45,895,680, 3 genes (within-gene range 0–2): CRHR1, MAPT-AS1, SPPL2C.
- chr17:63,477,061–63,548,977, 4 genes: ACE, AC113554.1, ACE3P, KCNH6.
- chr17:66,964,707–67,033,398, 3 genes: CACNG4, AC005544.1, AC005544.2.
- chr17:74,417,594–74,417,704, 1 gene: RNA5SP448.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:859,664–913,245, 3 genes, copy number 5–6: CFD, MED16, R3HDM4.

Autosomal genes at a single copy (total copy number 1): 5,469. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
